TCGA case TCGA-CG-4462 — Stomach Adenocarcinoma (TCGA-STAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach; Tissue source site: Indivumed. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e9ea3687-0db3-47f3-8099-b4fc054397f1

Demographics
Sex at birth: female; Country of residence at enrollment: Germany; Age at index: 72 years; Vital status: Dead; Days to death: 0 days.

Diagnoses (1)
1. Carcinoma, diffuse type: ICD-O-3 morphology code: 8145/3; ICD-10 code: C16.9; Tissue or organ of origin: Stomach, NOS; Site of resection or biopsy: Stomach, NOS; Classification of tumor: primary; Age at diagnosis: 72.6 years (26,511 days); Year of diagnosis: 2008; AJCC staging edition: 6th; AJCC pathologic T: T3; AJCC pathologic N: N3; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R2.
   Pathology details: Lymph nodes positive: 25; Lymph nodes tested: 25.

Follow-up (1 entry)
- Days to follow up: 0 days; Disease response: With Tumor.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-CG-4462-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.1; Intermediate dimension: 0.8; Shortest dimension: 0.2.
  Slide TCGA-CG-4462-01A-01-TS1: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 10.
  Slide TCGA-CG-4462-01A-01-BS1: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 10.
- Sample TCGA-CG-4462-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-CG-4462-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Stomach, Adenocarcinoma, Diffuse Type; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Lymph nodes examined: Yes; Cancer procurement city: Hamburg.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 0 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 0 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 0 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-CG-4462-01A-01D-1155-01): tumor purity 0.22, ploidy 2.08, whole-genome doublings 0.
